Surgical pathology report (de-identified scan), TCGA case TCGA-86-7713, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-7713-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Asterand Case ID	Open Clinica Subject ID	TCGA	Gross Description	Microscopic Description	Diagnosis Details
		86-7713			

[page 2 of 2]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 6 x 6 x 6 cm

Histologic type:

Adenocarcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/1 positive for metastasis (Regional 0/1)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant

treatment: Not specified

Additional pathologic findings:

Not specified

Comments: None

Date of Procurement

Source: NCI Genomic Data Commons file b6976323-c46a-482f-b4f6-825f7c1a12cf (TCGA-86-7713.0EC59EB0-0640-4D6B-B191-76BAD8BB38D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).